Somatic mutation profile of tumor specimen 0DFHEB from CCDI case PBBRGW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,134 days).
Specimen 0DFHEB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dad87d94-4b7b-4942-8c84-e5945cee29e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFHEG (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37a319cb-b596-4141-869a-7a83f109950a

The open-access MAF lists 8 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- B4GALNT2 | c.1016T>C p.M339T | Missense Mutation (SNP) | VAF 32/731 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs1424794858; called by muse, mutect2
- CHFR | c.38C>A p.P13Q | Missense Mutation (SNP) | VAF 110/252 reads (44%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1407689006, COSV57173272; called by muse, mutect2, varscan2
- LEPR | c.3056C>T p.P1019L | Missense Mutation (SNP) | VAF 320/693 reads (46%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as rs770114557, COSV62751209; called by muse, mutect2, varscan2
- RIMS2 | c.4123G>A p.V1375M (on ENST00000666250 / NM_001348490.2; = p.V946M on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 379/886 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs377163259; called by muse, mutect2, varscan2
- SHF | c.1013G>A p.R338Q | Missense Mutation (SNP) | VAF 63/483 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.19); catalogued as rs893653065; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 38/1011 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- FSIP2 | c.20074A>G p.K6692E | Missense Mutation (SNP) | VAF 32/914 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.391); called by muse, mutect2
- RUNX3 | c.492G>A p.A164= | Silent (SNP) | VAF 171/390 reads (44%) | catalogued as rs747875177; called by muse, mutect2, varscan2
